Somatic mutation profile of tumor specimen TCGA-WE-A8K1-06A (aliquot TCGA-WE-A8K1-06A-21D-A372-08) from TCGA case TCGA-WE-A8K1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Superficial spreading melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.2 years (28,197 days).
Specimen TCGA-WE-A8K1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c616199f-f32d-4007-84d9-c04ab1446acf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8K1-10A (Blood Derived Normal), aliquot TCGA-WE-A8K1-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6a374b2-b3ec-466c-b4be-d6563a95761a

The open-access MAF lists 414 somatic variants for this specimen: 265 protein-altering or splice-affecting, 138 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 138, Nonsense Mutation 15, Intron 4, RNA 4, Splice Region 2, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNM1L | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057523861, COSV99846110; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 65/199 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1621A>C p.I541L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52707631, COSV99221315; called by muse, mutect2, varscan2
- ACSL6 | c.1625G>A p.G542E (on ENST00000379240; = p.G567E on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57299413; called by muse, mutect2, varscan2
- ADGRB2 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as rs200969192, COSV99926317; called by muse, mutect2, varscan2
- AGO1 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100940854; called by muse, mutect2
- AKAP12 | c.4838C>T p.S1613L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99483292; called by muse, mutect2
- ALG10 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1307829081, COSV99848154; called by muse, mutect2, varscan2
- ALOX5 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); catalogued as COSV100980074; called by muse, mutect2, varscan2
- ALPK3 | c.4384G>A p.G1462S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs768268907, COSV99360984; called by muse, mutect2, varscan2
- ANAPC16 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1484504911, COSV100191920; called by muse, mutect2, varscan2
- ANAPC2 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as rs866845913, COSV100119088; called by mutect2, varscan2
- ANK3 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs751571796, COSV55053975; called by muse, mutect2, varscan2
- ANK3 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780139; called by muse, mutect2, varscan2
- ANK3 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267602542, COSV55046002, COSV99777574; called by muse, mutect2, varscan2
- ANXA1 | c.985-2A>T p.X329_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as rs879152305, COSV99973951; called by muse, mutect2, varscan2
- ANXA13 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1288237211, COSV99146029; called by muse, mutect2, varscan2
- ANXA13 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99146137; called by muse, mutect2, varscan2
- APOA4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as rs145184607; called by muse, mutect2, varscan2
- ARFGEF3 | c.2354G>A p.W785* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99293567; called by muse, mutect2, varscan2
- ARMC4 | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776670080, COSV59464456; called by muse, mutect2, varscan2
- ATP1A1 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99814507; called by muse, mutect2, varscan2
- BAAT | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99408504; called by muse, mutect2, varscan2
- BAZ2A | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.096); catalogued as COSV51630801, COSV99466279; called by muse, mutect2, varscan2
- BCL2L10 | c.560T>A p.F187Y | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99548572; called by muse, mutect2, varscan2
- BCORL1 | c.2899G>T p.G967C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99499659; called by muse, mutect2, varscan2
- BIN2 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.28); catalogued as rs1272937553, COSV99909411; called by muse, mutect2, varscan2
- CACNA1E | c.4502C>T p.S1501F | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62404058; called by muse, mutect2, varscan2
- CACNA1G | c.2785C>T p.L929F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661875; called by muse, mutect2
- CACNA2D3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs148102086; called by muse, mutect2, varscan2
- CAMTA1 | c.3407C>T p.A1136V | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373687956; called by muse, mutect2, varscan2
- CASP14 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 325/416 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as COSV99693037; called by muse, mutect2, varscan2
- CASR | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as rs1287075426, COSV56139780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAVIN2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV58423936; called by muse, mutect2, varscan2
- CCDC158 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs370067451; called by muse, mutect2, varscan2
- CCDC62 | c.1972C>T p.H658Y | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.093); catalogued as COSV99457196; called by muse, mutect2, varscan2
- CD1E | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV63769820, COSV63770568; called by muse, mutect2, varscan2
- CDCA7 | c.965C>T p.P322L (on ENST00000347703 / NM_145810.3; = p.P401L on NM_031942.5) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100143538; called by muse, mutect2, varscan2
- CEACAM5 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV99703929; called by muse, mutect2
- CENPN | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV100001352; called by muse, mutect2, varscan2
- CERS3 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as rs747911784, COSV52566853; called by muse, mutect2, varscan2
- CFAP77 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760052079, COSV100545855; called by muse, mutect2, varscan2
- CFTR | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99136403; called by muse, mutect2, varscan2
- CHRNA9 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758485973, COSV59575615; called by muse, mutect2
- CKAP4 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100952459; called by muse, mutect2, varscan2
- CLPTM1 | c.186-2A>T p.X62_splice | Splice Site (SNP) | VAF 17/113 reads (15%) | catalogued as COSV100493786, COSV61611538; called by muse, mutect2, varscan2
- CLVS1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100370046; called by muse, mutect2, varscan2
- CMYA5 | c.8125C>T p.P2709S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV101484059; called by muse, mutect2, varscan2
- CNOT4 | c.902C>T p.S301L (on ENST00000315544 / NM_001190848.1; = p.S298L on NM_013316.4) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100211637; called by muse, mutect2, varscan2
- CNTNAP2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as rs868783000, COSV62173390; called by muse, mutect2, varscan2
- COL1A1 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM070715, CM145061, COSV99867292; called by muse, mutect2, varscan2
- COL6A3 | c.8659A>T p.T2887S | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1373824728, COSV99798459; called by muse, mutect2, varscan2
- COPB2 | c.2693A>G p.N898S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs752359634, COSV100169082, COSV60351651; called by muse, mutect2, varscan2
- CRY2 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs1488054664, COSV101314592; called by muse, mutect2, varscan2
- CSMD1 | c.4180G>A p.D1394N (on ENST00000520002; = p.D1393N on NM_033225.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779702652, COSV59321276, COSV99045826; called by muse, mutect2, varscan2
- CSRNP3 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58777541; called by muse, mutect2, varscan2
- CUZD1 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100158833; called by muse, mutect2, varscan2
- CXADR | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99515324; called by muse, mutect2, varscan2
- CYP4F11 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99930867; called by mutect2, varscan2
- CYP4F11 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99930868; called by muse, mutect2, varscan2
- DCAF7 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60407292; called by muse, mutect2, varscan2
- DCLK3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs200470106, COSV69365481; called by muse, mutect2, varscan2
- DDX24 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1448635179, COSV58213763; called by muse, mutect2, varscan2
- DEAF1 | c.385C>T p.L129= | Splice Region (SNP) | VAF 14/59 reads (24%) | catalogued as rs1489312981, COSV100102054, COSV58607002; called by muse, mutect2, varscan2
- DHX32 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV99501683; called by muse, mutect2, varscan2
- DHX40 | c.1889A>T p.N630I | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52069315, COSV99233016; called by muse, mutect2, varscan2
- DLC1 | c.1690C>T p.P564S (on ENST00000276297 / NM_001348081.2; = p.P127S on NM_006094.5) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99363286; called by muse, mutect2, varscan2
- DNAH17 | c.7114C>T p.R2372* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as rs374930347; called by muse, mutect2, varscan2
- DNAH7 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56769872; called by muse, mutect2, varscan2
- DNAH9 | c.4299G>A p.M1433I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.381); catalogued as rs1471583348, COSV99303045; called by muse, mutect2, varscan2
- DPP3 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as rs535853041, COSV100855607; called by muse, mutect2, varscan2
- DPY19L2 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs754869560, COSV100116779; called by muse, mutect2, varscan2
- DSC1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99937678; called by muse, mutect2, varscan2
- DTX2 | c.1411T>G p.S471A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV100184619; called by muse, mutect2, varscan2
- DUS1L | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV100152493; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.773T>A p.L258H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99143661; called by muse, mutect2, varscan2
- DUT | c.487C>T p.P163S (on ENST00000331200 / NM_001025248.2; = p.P75S on NM_001948.4) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485252; called by muse, mutect2, varscan2
- EIF4G1 | c.2926C>T p.R976C (on ENST00000346169 / NM_198241.3; = p.R781C on NM_004953.5) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV59992382; called by muse, mutect2, varscan2
- ERBB4 | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs143134749; called by muse, mutect2, varscan2
- ERBB4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99624246; called by mutect2, varscan2
- ERN2 | c.703T>C p.W235R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99891579; called by muse, mutect2, varscan2
- FAM104A | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99278117; called by muse, mutect2, varscan2
- FAM104A | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767157414, COSV52146950; called by muse, mutect2, varscan2
- FAM71A | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54234603; called by muse, mutect2, varscan2
- FBXO30 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV99395211; called by muse, mutect2, varscan2
- FBXO31 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); catalogued as COSV61151514; called by muse, mutect2, varscan2
- FGA | c.455T>A p.I152N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100120401; called by muse, mutect2, varscan2
- FLG | c.10747G>A p.E3583K | Missense Mutation (SNP) | VAF 99/617 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as rs144652887; called by muse, mutect2, varscan2
- FLG | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.07); catalogued as COSV64242516, COSV64248152; called by muse, mutect2, varscan2
- FLRT2 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100420449; called by muse, mutect2, varscan2
- FPR3 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV59328730; called by muse, mutect2, varscan2
- FREM2 | c.7345C>T p.P2449S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as COSV99748923; called by muse, mutect2, varscan2
- FSCN3 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778757556, COSV99133759; called by muse, mutect2, varscan2
- FSIP2 | c.17866G>A p.E5956K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1167312627, COSV58082854; called by muse, mutect2, varscan2
- GHR | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV50115458, COSV99039096; called by muse, mutect2, varscan2
- GRID2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs367770083, COSV99940437; called by muse, mutect2, varscan2
- GRIN2C | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53111130, COSV99501018; called by muse, mutect2, varscan2
- GRIN3A | c.2386A>G p.T796A | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV100701516; called by muse, mutect2, varscan2
- GRM3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64469390; called by muse, mutect2, varscan2
- GSS | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99404438; called by muse, mutect2
- GTF3C1 | c.4213A>G p.I1405V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs369500732; called by muse, mutect2, varscan2
- GUCY2F | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs775683052, COSV54301117, COSV54301175; called by muse, mutect2, varscan2
- GZMK | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140814; called by muse, mutect2, varscan2
- HAO2 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58037988; called by muse, mutect2, varscan2
- HDAC9 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV67777093; called by muse, mutect2, varscan2
- HEPH | c.1268G>A p.R423Q (on ENST00000343002; = p.R156Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs748869673, COSV57958937; called by muse, mutect2, varscan2
- HNRNPD | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV58313811; called by muse, mutect2, varscan2
- HOOK2 | c.1906C>T p.R636* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs756409348, COSV99317593; called by muse, mutect2, varscan2
- HRNR | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 135/260 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1360220414, COSV100913508; called by muse, mutect2, varscan2
- HSPA12B | c.376T>A p.Y126N | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99654008; called by muse, mutect2, varscan2
- HTR3C | c.924C>T p.I308= | Splice Region (SNP) | VAF 21/111 reads (19%) | catalogued as COSV100570635, COSV100570671; called by muse, mutect2, varscan2
- HYDIN | c.15083G>A p.G5028D | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1275975750, COSV101125094; called by muse, mutect2, varscan2
- IFNA4 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV70180094; called by muse, mutect2, varscan2
- IL9R | c.977G>A p.W326* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99729844; called by muse, mutect2
- ITGBL1 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.905); catalogued as COSV101095410; called by muse, mutect2, varscan2
- KANSL1 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99294563; called by muse, mutect2
- KASH5 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101483448; called by muse, mutect2, varscan2
- KCND2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100474204, COSV58580855; called by muse, mutect2, varscan2
- KCNQ3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs1199073727, COSV101196158; called by muse, mutect2, varscan2
- KCNS2 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV54638208; called by muse, mutect2, varscan2
- KCNU1 | c.1444T>C p.F482L | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV101299238; called by muse, mutect2, varscan2
- KDR | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.887); catalogued as COSV55764736, COSV55772058; called by muse, mutect2, varscan2
- KEL | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100787094; called by muse, mutect2, varscan2
- KRT18 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs146080391, COSV101184027; called by muse, mutect2, varscan2
- KRT26 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs761696509, COSV59412831; called by muse, mutect2, varscan2
- LGI2 | c.1292C>T p.T431I | Missense Mutation (SNP) | VAF 73/360 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101180841; called by muse, mutect2, varscan2
- LINGO2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100430587; called by muse, mutect2, varscan2
- LRRTM3 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV63662643, COSV63663752; called by muse, mutect2, varscan2
- MARCHF6 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929742; called by muse, mutect2, varscan2
- MAST3 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99445411; called by muse, mutect2, varscan2
- MATN4 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | PolyPhen probably damaging (0.909); catalogued as rs1157381506, COSV100637037; called by muse, mutect2, varscan2
- MGAM | c.2174C>T p.T725I | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72075835; called by muse, mutect2, varscan2
- MGAT4C | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100152990; called by muse, mutect2, varscan2
- MIA3 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60511655; called by muse, mutect2, varscan2
- MIB2 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100598920; called by muse, mutect2
- MIGA1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100889779; called by muse, mutect2, varscan2
- MIPEP | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV101193125; called by muse, mutect2, varscan2
- MOGAT3 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.489); catalogued as COSV99777164; called by muse, mutect2
- MRAS | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56673787; called by muse, mutect2, varscan2
- MRPL58 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.588); catalogued as COSV100043013; called by muse, mutect2, varscan2
- MRTFB | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV100371326; called by muse, mutect2, varscan2
- MTNR1B | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99925124; called by muse, mutect2, varscan2
- MTRF1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs376093788, COSV101067514; called by muse, mutect2, varscan2
- MTUS2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1443904265, COSV70912573; called by muse, mutect2, varscan2
- MUC16 | c.42554G>A p.S14185N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV66691478; called by muse, mutect2, varscan2
- MUC17 | c.11957C>T p.S3986L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs1562819680, COSV100073438; called by muse, mutect2, varscan2
- MYO9A | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1307006954, COSV61848277; called by muse, mutect2, varscan2
- MYPN | c.557A>C p.E186A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV100590025; called by muse, mutect2, varscan2
- NBAS | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV99869890; called by muse, mutect2, varscan2
- NEBL | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV101009220; called by muse, mutect2, varscan2
- NID2 | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV53497417, COSV99356589; called by muse, mutect2
- NIPAL4 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV61731181; called by muse, mutect2, varscan2
- NLRP10 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762414203, COSV60778851; called by muse, mutect2, varscan2
- NLRP8 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV52594918; called by muse, mutect2, varscan2
- NLRP9 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV60463477; called by muse, mutect2, varscan2
- NME8 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as COSV99553354; called by muse, mutect2, varscan2
- NOTCH3 | c.6084T>A p.S2028R | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs1179087884, COSV99657337; called by muse, mutect2, varscan2
- NPC1L1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs769471545, COSV99211547; called by muse, mutect2, varscan2
- NTNG2 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs902068183, COSV100647475; called by muse, mutect2, varscan2
- OR10A3 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.372); catalogued as rs1483243253, COSV100660274; called by muse, mutect2, varscan2
- OR10A7 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 35/209 reads (17%) | catalogued as COSV100406570; called by muse, mutect2, varscan2
- OR10K2 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV59220448; called by muse, mutect2, varscan2
- OR13C3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764550950, COSV101053323; called by muse, mutect2, varscan2
- OR1Q1 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV99939249; called by muse, mutect2, varscan2
- OR2D2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55057259; called by muse, mutect2
- OR2Z1 | c.812A>G p.D271G | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1295576029, COSV100136433; called by muse, mutect2, varscan2
- OR4X1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201997353, COSV60723840; called by muse, mutect2, varscan2
- ORC1 | c.1620G>C p.K540N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856674; called by muse, mutect2, varscan2
- P2RY12 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1309279839, COSV99853280; called by muse, mutect2, varscan2
- PADI1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.275); catalogued as rs372107973; called by muse, mutect2, varscan2
- PAPLN | c.2024G>A p.G675E (on ENST00000554301; = p.G648E on NM_173462.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220296380, COSV99389718; called by muse, mutect2, varscan2
- PATJ | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100334300; called by muse, mutect2, varscan2
- PATJ | c.2501G>A p.G834E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100334303; called by muse, mutect2, varscan2
- PAX2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100695192; called by muse, mutect2, varscan2
- PCDHB13 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV99507318; called by muse, mutect2, varscan2
- PLCZ1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV99856396; called by muse, mutect2, varscan2
- POU6F2 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs1422798509, COSV68871864; called by muse, mutect2, varscan2
- PPM1K | c.238A>C p.S80R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV99900997; called by muse, mutect2, varscan2
- PRKAA2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457982338, COSV100982839, COSV64804139; called by muse, mutect2, varscan2
- PRKCZ | c.730T>C p.S244P | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV101057771; called by muse, mutect2, varscan2
- PRKG1 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as COSV100907273; called by muse, mutect2, varscan2
- PRLR | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99184420; called by muse, mutect2, varscan2
- PRND | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59896082; called by muse, mutect2, varscan2
- PROS1 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762438750, CM951057, COSV101260517; called by muse, mutect2, varscan2
- PRPF8 | c.6569C>T p.P2190L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100025446; called by muse, mutect2, varscan2
- PSG4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 91/421 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755537243, COSV54941937; called by muse, mutect2, varscan2
- PTPRD | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61937192, COSV61946549; called by muse, mutect2, varscan2
- PTPRN | c.2182A>G p.T728A | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99834022; called by muse, mutect2, varscan2
- RBSN | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99515262; called by muse, mutect2, varscan2
- RDH16 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as rs756909031, COSV100660116; called by muse, mutect2, varscan2
- RELN | c.8393C>A p.P2798Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV99067084; called by muse, mutect2, varscan2
- RFX6 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60587780; called by muse, mutect2, varscan2
- RP1 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99607597; called by muse, mutect2, varscan2
- RYR3 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481330554, COSV101212855; called by muse, mutect2, varscan2
- SAMD7 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs773467385, COSV100156945; called by muse, mutect2, varscan2
- SCMH1 | c.1229C>T p.T410I (on ENST00000326197 / NM_001031694.2; = p.T363I on NM_012236.4) | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV100401777; called by muse, mutect2, varscan2
- SELE | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0.022); catalogued as COSV100324796; called by muse, mutect2, varscan2
- SEMA3F | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs1195031315, COSV99137460; called by muse, mutect2, varscan2
- SFXN1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as rs762989628, COSV58494325; called by muse, mutect2, varscan2
- SIN3A | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845156; called by muse, mutect2, varscan2
- SKP2 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as rs1281317825, COSV99682869; called by muse, mutect2, varscan2
- SLC22A7 | c.691G>A p.V231M (on ENST00000372585 / NM_153320.2; = p.V229M on NM_006672.3) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as rs757209300, COSV65353641; called by muse, mutect2, varscan2
- SLC22A9 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1319120357, COSV99655035; called by muse, mutect2, varscan2
- SLC39A12 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1226517271, COSV101069768, COSV66198279; called by muse, mutect2, varscan2
- SLC5A6 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100143312; called by muse, mutect2, varscan2
- SLC6A18 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99722344; called by muse, mutect2, varscan2
- SLIT3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749757252, COSV60607442; called by muse, mutect2, varscan2
- SMG1 | c.10340C>T p.P3447L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs749231051, COSV67170822; called by muse, mutect2, varscan2
- SMG1 | c.10339C>T p.P3447S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.086); catalogued as COSV101246071; called by muse, mutect2, varscan2
- SMOX | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99603215; called by muse, mutect2, varscan2
- SNRPD1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572142783, COSV100303443; called by muse, mutect2, varscan2
- SOGA3 | c.2723C>T p.S908F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100846932, COSV64108736; called by muse, mutect2, varscan2
- SPEF2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV56801741; called by muse, mutect2, varscan2
- SULF1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769577350, COSV52673496, COSV52687237; called by muse, mutect2, varscan2
- SYNE1 | c.17510C>A p.P5837H (on ENST00000367255 / NM_182961.4; = p.P5766H on NM_033071.3) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV99565411; called by muse, mutect2, varscan2
- SYNE1 | c.8087A>G p.N2696S (on ENST00000367255 / NM_182961.4; = p.N2703S on NM_033071.3) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs771577783, COSV54983221; called by muse, mutect2, varscan2
- SYT10 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57340633; called by muse, mutect2, varscan2
- TAF1L | c.5189G>A p.G1730E | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as rs267602207, COSV99644762; called by muse, mutect2, varscan2
- TBC1D1 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV54726176; called by muse, mutect2, varscan2
- TBRG4 | c.1780T>C p.F594L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99345428; called by muse, mutect2, varscan2
- TBX15 | c.688G>A p.G230R (on ENST00000369429 / NM_001330677.2; = p.G124R on NM_152380.3) | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99254212; called by muse, mutect2, varscan2
- TBX18 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.079); catalogued as COSV100858517; called by muse, mutect2, varscan2
- TENM3 | c.3933T>A p.N1311K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV101305145; called by muse, mutect2
- TGFB3 | c.424A>T p.N142Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1421008373, COSV99472546; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99305134; called by muse, mutect2
- TGM6 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs761100219, COSV99171799; called by muse, mutect2, varscan2
- TM4SF5 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV54495787; called by muse, mutect2, varscan2
- TMEM139 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100131006; called by muse, mutect2, varscan2
- TNFRSF11B | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs145544246; called by muse, mutect2, varscan2
- TNXB | c.10676T>C p.L3559P (on ENST00000647633; = p.L3312P on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.951); catalogued as COSV100926364; called by muse, mutect2, varscan2
- TPRG1L | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1260170218, COSV99573322; called by muse, mutect2, varscan2
- TRANK1 | c.5879C>T p.S1960F | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100081189; called by muse, mutect2, varscan2
- TRIM25 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as rs772478621, COSV57544183; called by muse, mutect2, varscan2
- TRIM40 | c.643G>A p.E215K (on ENST00000376724; = p.E186K on NM_138700.4) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV57157732; called by muse, mutect2, varscan2
- TSHR | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99991917; called by muse, mutect2, varscan2
- TSNAXIP1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs555332209, COSV99535116; called by muse, mutect2, varscan2
- TTLL5 | c.449T>G p.F150C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1394547348, COSV99709631; called by muse, mutect2, varscan2
- TTN | c.91613T>A p.V30538E (on ENST00000591111; = p.V23114E on NM_003319.4) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | PolyPhen probably damaging (0.998); catalogued as COSV100614574; called by muse, mutect2, varscan2
- TTN | c.45773G>A p.W15258* (on ENST00000591111; = p.W7834* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/154 reads (12%) | catalogued as COSV100614580; called by muse, mutect2, varscan2
- TULP4 | c.3881C>A p.P1294Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as rs1209701683, COSV100893520; called by muse, mutect2, varscan2
- TYW1 | c.1669C>T p.L557F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100658721; called by muse, mutect2, varscan2
- UBR5 | c.7454G>T p.R2485L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.272); catalogued as COSV55294010, COSV99640952; called by muse, mutect2, varscan2
- UBTF | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 45/126 reads (36%) | catalogued as rs1216025875, COSV57186068; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3931G>A p.V1311M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs1202897978, COSV99511939; called by muse, mutect2, varscan2
- USH2A | c.12602G>A p.G4201E | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV100235319; called by muse, mutect2, varscan2
- WDR49 | c.1904C>T p.P635L (on ENST00000308378 / NM_001366158.1; = p.P976L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV100392861; called by muse, mutect2, varscan2
- WDR49 | c.785G>A p.R262Q (on ENST00000308378 / NM_001366158.1; = p.R603Q on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs538758282, COSV100392863, COSV57718577; called by muse, mutect2, varscan2
- WNT5A | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.179); catalogued as rs776543464, COSV99224887; called by muse, varscan2
- WNT7A | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs761294840, COSV53200798; called by muse, mutect2, varscan2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XIRP2 | c.3430C>T p.Q1144* (on ENST00000628543; = p.Q1319* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99743240; called by muse, mutect2, varscan2
- XKRX | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV60709289; called by muse, mutect2, varscan2
- ZCWPW1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV61249628; called by muse, mutect2, varscan2
- ZFYVE16 | c.1999A>T p.K667* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100566404; called by muse, mutect2, varscan2
- ZMYM6 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.579); catalogued as COSV58185042; called by muse, mutect2, varscan2
- ZNF157 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs150024660, COSV100998502, COSV89038855; called by muse, mutect2, varscan2
- ZNF234 | c.1904G>T p.R635L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.151); catalogued as COSV101468368; called by muse, mutect2, varscan2
- ZNF804A | c.2677G>A p.G893S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100167366, COSV100168082; called by muse, mutect2
- ZNF831 | c.4178G>A p.R1393Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs753837433, COSV64037136; called by muse, mutect2, varscan2
- ZNF836 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 93/298 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as rs767831643, COSV100440963; called by muse, mutect2, varscan2
- MIER3 | c.174_176delinsG p.E59Kfs*17 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by pindel, varscan2*
- PRAMEF10 | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF19 | c.1389_1391dup p.P464dup | In Frame Ins (INS) | VAF 72/250 reads (29%) | called by mutect2, pindel, varscan2
- PRKD3 | c.2363_2364dup p.A789Mfs*21 | Frame Shift Ins (INS) | VAF 9/66 reads (14%) | called by mutect2, pindel
- SYNRG | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABCE1 | c.1695A>T p.T565= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV99668580; called by muse, mutect2, varscan2
- ADGRV1 | c.11478C>T p.V3826= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs777384335, COSV101316024; called by muse, mutect2, varscan2
- AGAP6 | c.1935C>T p.S645= (on ENST00000374056 / NM_001365867.1; = p.S668= on NM_001077665.2) | Silent (SNP) | VAF 12/43 reads (28%) | called by mutect2, varscan2
- ALPI | c.879G>A p.T293= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs776533953, COSV55013425; called by muse, mutect2, varscan2
- ANAPC16 | c.66T>A p.G22= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV100191921; called by muse, mutect2, varscan2
- ANKRD30A | c.543G>A p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as rs748801395, COSV64609214, COSV64609913; called by muse, mutect2, varscan2
- AP000311.1 | c.204C>T p.I68= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs267606117, COSV51707873; called by muse, mutect2, varscan2
- ARSG | c.16C>T p.L6= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV101477896; called by muse, mutect2, varscan2
- ATAD3B | c.727C>T p.L243= (on ENST00000308647; = p.L349= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV100426488; called by muse, mutect2, varscan2
- ATP13A5 | c.1929C>T p.F643= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs865991586, COSV60872697, COSV60874815; called by muse, mutect2, varscan2
- ATP8A2 | c.2688C>T p.F896= | Silent (SNP) | VAF 40/212 reads (19%) | catalogued as rs201549197; called by muse, mutect2, varscan2
- BAZ1B | c.294C>T p.S98= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV100289807; called by muse, mutect2, varscan2
- BIRC3 | c.285C>T p.F95= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99679934; called by muse, mutect2, varscan2
- BPIFB6 | c.774C>T p.L258= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as rs780411105, COSV100848520; called by muse, mutect2, varscan2
- BRMS1 | c.660C>T p.I220= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs757130904, COSV100254684; called by muse, mutect2, varscan2
- C10orf71 | c.1134G>A p.Q378= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV60511954; called by muse, mutect2, varscan2
- CCDC62 | c.1971C>T p.S657= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs1243415267, COSV53431947; called by muse, mutect2, varscan2
- CILP | c.2604G>A p.R868= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as COSV56022006; called by muse, mutect2, varscan2
- CIR1 | c.210C>T p.F70= | Silent (SNP) | VAF 49/273 reads (18%) | catalogued as rs1427371040, COSV100564988; called by muse, mutect2, varscan2
- COL20A1 | c.3702C>T p.P1234= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs767100958, COSV58924291; called by muse, mutect2, varscan2
- COL6A3 | c.8658A>T p.T2886= | Silent (SNP) | VAF 44/219 reads (20%) | catalogued as COSV99798462; called by muse, mutect2, varscan2
- CPXCR1 | c.372C>T p.F124= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV52161985; called by muse, mutect2, varscan2
- CPZ | c.975C>T p.F325= (on ENST00000360986 / NM_001014447.3; = p.F314= on NM_003652.3) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV59921330; called by muse, mutect2, varscan2
- CSMD2 | c.8181C>T p.I2727= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99590390; called by muse, mutect2, varscan2
- CT83 | c.18C>T p.L6= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV64140978; called by muse, mutect2, varscan2
- CTNND2 | c.564C>T p.L188= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV58874713; called by muse, mutect2, varscan2
- CYP4F2 | c.306C>T p.C102= | Silent (SNP) | VAF 29/245 reads (12%) | catalogued as rs1192579784, COSV50000381; called by muse, mutect2, varscan2
- DCDC1 | c.2091T>C p.P697= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs1347372031, COSV100663466; called by muse, mutect2, varscan2
- DDX54 | c.672C>T p.P224= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as rs373367841; called by muse, mutect2, varscan2
- DLC1 | c.1689C>T p.V563= (on ENST00000276297 / NM_001348081.2; = p.V126= on NM_006094.5) | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV52299974; called by muse, mutect2, varscan2
- DNAH11 | c.12141A>G p.E4047= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100179353; called by muse, mutect2, varscan2
- DNAH2 | c.2289G>A p.L763= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101209346; called by muse, mutect2, varscan2
- DNER | c.1953C>T p.I651= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100519137, COSV59165708; called by muse, mutect2, varscan2
- EPAS1 | c.849G>C p.A283= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99763252; called by muse, mutect2, varscan2
- ERC2 | c.291C>T p.A97= | Silent (SNP) | VAF 87/193 reads (45%) | catalogued as COSV99885183; called by muse, mutect2, varscan2
- EVPL | c.2886C>T p.F962= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100044590; called by muse, mutect2, varscan2
- F7 | c.1350C>T p.L450= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100661027; called by muse, mutect2, varscan2
- FAT4 | c.2598A>T p.V866= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV101272358; called by muse, mutect2, varscan2
- FERMT1 | c.657C>T p.L219= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs150419419; called by muse, mutect2, varscan2
- FGD1 | c.2619C>T p.F873= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs375328916, COSV64308336; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- FLG | c.11244C>T p.H3748= | Silent (SNP) | VAF 287/558 reads (51%) | catalogued as rs377272004, COSV64240729; called by muse, mutect2, varscan2
- FPR3 | c.765C>T p.F255= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV59332494; called by muse, mutect2, varscan2
- FUT7 | c.1014T>C p.G338= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99687717; called by muse, mutect2, varscan2
- GABRB2 | c.1275A>G p.G425= (on ENST00000274547; = p.G387= on NM_000813.3) | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV99196102; called by muse, mutect2, varscan2
- GABRR1 | c.864T>C p.T288= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV101033930; called by muse, mutect2, varscan2
- GBF1 | c.318A>T p.A106= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100890504; called by muse, mutect2, varscan2
- GLRB | c.483C>T p.I161= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as COSV52421886; called by muse, mutect2, varscan2
- GPR158 | c.2958C>A p.A986= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs769142622, COSV66267722; called by muse, mutect2, varscan2
- GRIK5 | c.1611C>T p.S537= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99490608; called by mutect2, varscan2
- GRXCR1 | c.231G>A p.Q77= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs368876169, COSV101295693; called by muse, mutect2, varscan2
- GTF3C2 | c.1653C>T p.P551= | Silent (SNP) | VAF 48/178 reads (27%) | catalogued as COSV99272811; called by muse, mutect2, varscan2
- HABP2 | c.510G>A p.R170= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV100667941; called by muse, mutect2, varscan2
- HCAR2 | c.333C>T p.R111= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100186509; called by muse, mutect2, varscan2
- HIC1 | c.102G>A p.L34= (on ENST00000322941 / NM_001098202.1; = p.L15= on NM_006497.4) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs202126573, COSV99558236; called by muse, mutect2
- HRNR | c.6588C>T p.S2196= | Silent (SNP) | VAF 124/992 reads (13%) | catalogued as rs1345475423, COSV100913506, COSV64259388; called by muse, varscan2
- IGHV2-70 | c.105G>A p.Q35= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs559969703; called by muse, mutect2, varscan2
- IL1RAP | c.597C>T p.F199= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV99299728; called by muse, mutect2, varscan2
- ILDR2 | c.924C>T p.S308= | Silent (SNP) | VAF 81/163 reads (50%) | catalogued as COSV54836435; called by muse, mutect2, varscan2
- ITGAE | c.816C>T p.I272= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV99561001; called by muse, mutect2, varscan2
- ITIH4 | c.2064C>T p.R688= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs1303851197, COSV99819443; called by muse, mutect2, varscan2
- KASH5 | c.588C>T p.R196= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV101483446; called by muse, mutect2, varscan2
- KCNJ8 | c.624C>T p.F208= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs1481907365, COSV53715206, COSV99557585; called by muse, mutect2, varscan2
- KLHL4 | c.672G>A p.R224= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100909621; called by muse, mutect2, varscan2
- KRT74 | c.849C>T p.I283= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs556767276, COSV99977539; called by muse, mutect2, varscan2
- KRTAP12-2 | c.126C>T p.S42= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs1555944878, COSV100553739; called by muse, mutect2, varscan2
- LCN8 | c.390C>T p.L130= (on ENST00000612714 / NM_001345934.1; = p.L107= on NM_178469.3) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100293424; called by muse, mutect2, varscan2
- LNPEP | c.2454G>A p.E818= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99183537; called by muse, mutect2, varscan2
- LTBP2 | c.1504C>T p.L502= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100000375, COSV100000419; called by muse, mutect2
- MAGEA1 | c.441C>T p.A147= | Silent (SNP) | VAF 78/128 reads (61%) | catalogued as COSV100756651; called by muse, mutect2, varscan2
- MAP3K21 | c.945G>A p.V315= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100786276; called by muse, mutect2, varscan2
- MECOM | c.2502G>A p.A834= (on ENST00000468789 / NM_001105078.4; = p.A1022= on NM_004991.4) | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs779331325, COSV52958403; called by muse, mutect2, varscan2
- MED15 | c.720A>G p.R240= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99487723; called by muse, mutect2, varscan2
- MROH7 | c.267C>T p.I89= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs375679935; called by muse, mutect2, varscan2
- MROH7 | c.3264C>T p.I1088= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100273515; called by muse, mutect2, varscan2
- MUC16 | c.20673G>A p.V6891= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV101200019; called by muse, mutect2, varscan2
- MYH13 | c.5436G>A p.G1812= | Silent (SNP) | VAF 58/168 reads (35%) | catalogued as rs1473727024, COSV52824010; called by muse, mutect2, varscan2
- NCR1 | c.768C>T p.L256= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV52557858; called by muse, mutect2, varscan2
- NLGN4Y | c.1773G>A p.L591= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as COSV100196848; called by muse, mutect2, varscan2
- NRK | c.4272G>A p.K1424= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV54601830, COSV99687912; called by muse, mutect2, varscan2
- NXPE4 | c.405G>A p.G135= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs780177321, COSV100970450; called by muse, mutect2, varscan2
- ODF1 | c.177C>T p.S59= | Silent (SNP) | VAF 52/229 reads (23%) | catalogued as COSV99574208; called by muse, mutect2, varscan2
- OR13C9 | c.378C>T p.I126= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV99403454; called by muse, mutect2, varscan2
- OR14C36 | c.33C>T p.L11= | Silent (SNP) | VAF 30/222 reads (14%) | catalogued as COSV100507548; called by muse, mutect2, varscan2
- OR4N5 | c.90A>G p.L30= | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as rs1213381366, COSV100374110; called by muse, mutect2, varscan2
- OR5D13 | c.885G>A p.R295= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1295811448, COSV62332673; called by muse, mutect2, varscan2
- PARD6G | c.42C>T p.Y14= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1456106576, COSV100783411; called by muse, mutect2, varscan2
- PCDHB3 | c.1293G>A p.L431= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as rs1453280529, COSV99165251; called by muse, mutect2, varscan2
- PCNX2 | c.708G>A p.Q236= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs1445654981, COSV99267781; called by muse, mutect2, varscan2
- PDCD11 | c.585C>T p.S195= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs756422861, COSV100874348; called by muse, mutect2, varscan2
- PDZRN3 | c.1914C>T p.I638= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as rs374714693; called by muse, mutect2, varscan2
- PKHD1L1 | c.3189C>T p.S1063= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV65749034; called by muse, mutect2, varscan2
- PKMYT1 | c.576C>T p.P192= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1567386931, COSV99234089; called by muse, mutect2, varscan2
- PLEC | c.12648C>T p.I4216= (on ENST00000322810 / NM_201380.4; = p.I4106= on NM_000445.5) | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV59645120; called by muse, mutect2, varscan2
- PLEK2 | c.519C>T p.F173= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs766030830, COSV53607149; called by muse, mutect2, varscan2
- PNO1 | c.228G>A p.R76= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99718310; called by muse, mutect2, varscan2
- PRDM11 | c.39C>T p.I13= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs757275466, COSV55439876, COSV99770744; called by muse, mutect2, varscan2
- PRTG | c.1713G>A p.G571= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV101221391; called by muse, mutect2, varscan2
- PSD | c.675C>T p.P225= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1224827827, COSV99192727; called by muse, mutect2, varscan2
- PTPRN | c.1422C>T p.I474= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs778155767, COSV55348033; called by muse, mutect2, varscan2
- RASA3 | c.315C>T p.Y105= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as rs1364111685, COSV100480586; called by muse, mutect2, varscan2
- RBM46 | c.1596C>T p.F532= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV99908127; called by muse, mutect2, varscan2
- RBSN | c.2067C>T p.P689= | Silent (SNP) | VAF 36/237 reads (15%) | catalogued as rs1387110946, COSV53795236, COSV99515259; called by muse, mutect2, varscan2
- RELN | c.10122C>T p.I3374= | Silent (SNP) | VAF 29/171 reads (17%) | catalogued as rs767729538, COSV100633836; ClinVar: likely benign; called by muse, mutect2, varscan2
- RESF1 | c.1215G>A p.Q405= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV100440371; called by muse, mutect2, varscan2
- ROR2 | c.327C>T p.I109= | Silent (SNP) | VAF 42/205 reads (20%) | catalogued as COSV100995841; called by muse, mutect2, varscan2
- RORB | c.1113T>A p.A371= (on ENST00000396204 / NM_001365023.1; = p.A360= on NM_006914.4) | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100974349; called by muse, mutect2, varscan2
- RPP40 | c.960C>T p.S320= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100123987, COSV60293174; called by muse, mutect2, varscan2
- RPTOR | c.870C>T p.V290= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100156293; called by muse, mutect2, varscan2
- RYR3 | c.2121C>T p.D707= | Silent (SNP) | VAF 42/234 reads (18%) | catalogued as rs369220734; called by muse, mutect2, varscan2
- SACM1L | c.1200G>A p.Q400= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV101203770; called by muse, mutect2, varscan2
- SCN9A | c.3864C>T p.S1288= (on ENST00000303354; = p.S1277= on NM_002977.3) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100312951; called by muse, mutect2
- SERPINI2 | c.573G>A p.Q191= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52984678; called by muse, mutect2, varscan2
- SEZ6L2 | c.1974C>T p.S658= (on ENST00000308713 / NM_001114099.3; = p.S588= on NM_012410.4) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100435435; called by muse, mutect2, varscan2
- SLC27A2 | c.1827C>T p.I609= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV99982848; called by muse, mutect2, varscan2
- SLC39A1 | c.873C>T p.I291= | Silent (SNP) | VAF 84/141 reads (60%) | catalogued as COSV100135498; called by muse, mutect2, varscan2
- SLC46A3 | c.306C>T p.F102= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57182961; called by muse, mutect2, varscan2
- SLC4A5 | c.2514C>T p.P838= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs373675468; called by muse, mutect2, varscan2
- SLC5A7 | c.22C>T p.L8= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99886700; called by muse, mutect2, varscan2
- SLX4 | c.3039A>G p.E1013= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99568055; called by muse, mutect2, varscan2
- SPEN | c.10647C>T p.I3549= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs780849980, COSV65269520; called by muse, mutect2, varscan2
- SUGP1 | c.1026C>T p.A342= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV99895109; called by muse, mutect2, varscan2
- SUPT6H | c.5142T>A p.A1714= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs1231979772, COSV99972714; called by muse, mutect2, varscan2
- TEAD1 | c.969C>T p.S323= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100532431; called by muse, mutect2, varscan2
- THSD4 | c.1290C>T p.V430= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs181734399; called by muse, mutect2, varscan2
- TINAGL1 | c.87G>A p.R29= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99592895; called by muse, mutect2, varscan2
- TMEM63B | c.1203C>T p.S401= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52477179; called by muse, mutect2, varscan2
- TNXB | c.3771G>A p.G1257= (on ENST00000647633; = p.G1010= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100926365; called by muse, mutect2, varscan2
- TOM1L1 | c.390C>T p.F130= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as COSV100779219; called by muse, mutect2, varscan2
- TRAV8-3 | c.174C>T p.S58= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- TRAV9-1 | c.153C>T p.S51= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.97803G>A p.K32601= (on ENST00000591111; = p.K25177= on NM_003319.4) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100614564, COSV60352896; called by muse, mutect2, varscan2
- TTN | c.4263G>A p.R1421= (on ENST00000591111; = p.R1375= on NM_003319.4) | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV59889382; called by muse, mutect2, varscan2
- TUBG1 | c.342C>T p.I114= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV99258701; called by muse, mutect2, varscan2
- VIL1 | c.2091G>A p.V697= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99945559; called by muse, varscan2
- VPS33A | c.576C>T p.I192= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs142148462, COSV57359054; called by muse, mutect2, varscan2
- VPS4A | c.885G>A p.E295= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1231976476, COSV99651994; called by muse, mutect2, varscan2
- ZNF350 | c.219C>T p.I73= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as COSV99702558; called by muse, mutect2, varscan2
- ZNF804B | c.2505C>T p.S835= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100303972; called by muse, mutect2, varscan2
- AL590867.2 | n.222C>G | RNA (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178055774 C>T | 3'Flank (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- GAB1 | c.1586-1673C>T | Intron (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99528360; called by muse, mutect2, varscan2
- HERC2P3 | n.560G>A | RNA (SNP) | VAF 14/67 reads (21%) | called by mutect2, varscan2
- MROH8 | c.370+2474C>T | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99457342; called by muse, mutect2, varscan2
- OR2U1P | n.624C>T | RNA (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- PLOD1 | c.741+83C>T | Intron (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157618 G>A | 5'Flank (SNP) | VAF 16/54 reads (30%) | catalogued as rs1257609712; called by muse, mutect2, varscan2
- SNORD115-18 | n.33A>G | RNA (SNP) | VAF 69/373 reads (18%) | called by muse, mutect2, varscan2
- SYTL2 | c.1460-3120C>T | Intron (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100314313; called by muse, mutect2, varscan2
- XIRP2 | c.*252G>A | 3'UTR (SNP) | VAF 11/52 reads (21%) | catalogued as rs748455683, COSV99743242; called by muse, mutect2, varscan2
